Somatic mutation profile of tumor specimen MP2PRT-PAUFFJ-TMP1-A (aliquot MP2PRT-PAUFFJ-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUFFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (1,994 days).
Specimen MP2PRT-PAUFFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de6a75a1-9a14-4c08-a3da-a097a11cafc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFFJ-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59ced30b-fb53-4039-9013-3827b3924623

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 15/386 reads (4%) | catalogued as rs1244556535; called by muse, mutect2
- JMJD1C | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59514103; called by muse, mutect2
- PAF1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 102/152 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99655632; called by muse, mutect2, varscan2
- CRP | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 184/518 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CRPPA | c.1352C>T p.A451V (on ENST00000407010 / NM_001368197.1; = p.A401V on NM_001101417.4) | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- FOXP4 | c.1738G>A p.E580K (on ENST00000307972 / NM_001012426.1; = p.E567K on NM_138457.3) | Missense Mutation (SNP) | VAF 167/496 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CSTF2 | c.1590C>T p.V530= | Silent (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
